CCDI case PBCNEA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Other and unspecified male genital organs.
https://portal.gdc.cancer.gov/cases/f07c055d-8f13-4aad-b4f4-a9edfbe23b9e

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Descended testis; Age at diagnosis: 3.6 years (1,310 days).

Biospecimens (3 samples)
- Sample 0DVU3D: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DVU3I: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DVU3V: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
